Somatic mutation profile of tumor specimen TCGA-TM-A7C5-01A (aliquot TCGA-TM-A7C5-01A-11D-A32B-08) from TCGA case TCGA-TM-A7C5, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 30.9 years (11,286 days).
Specimen TCGA-TM-A7C5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 189361ee-fec5-48ff-8da0-bac830079379.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TM-A7C5-10A (Blood Derived Normal), aliquot TCGA-TM-A7C5-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c808679-034b-48b5-8fdc-8d86fc780399

The open-access MAF lists 25 somatic variants for this specimen: 23 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Nonsense Mutation 4, Frame Shift Del 2, 3'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 26/62 reads (42%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ATRN | c.3913C>T p.Q1305* | Nonsense Mutation (SNP) | VAF 18/71 reads (25%) | catalogued as COSV99497784; called by muse, mutect2, varscan2
- CIB1 | c.308C>T p.T103M | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs147405990; called by muse, mutect2, varscan2
- CIC | c.755T>C p.L252P | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99360215; called by muse, mutect2, varscan2
- CPAMD8 | c.4361G>A p.R1454Q (on ENST00000651564; = p.R1407Q on NM_015692.5) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.063); catalogued as rs565062781, COSV101488489; called by muse, mutect2, varscan2
- EPHB4 | c.368C>A p.A123D | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100639634; called by muse, varscan2
- FAM172A | c.218T>G p.L73* | Nonsense Mutation (SNP) | VAF 67/144 reads (47%) | catalogued as COSV101232932; called by muse, mutect2, varscan2
- KIR2DL4 | c.391G>T p.A131S (on ENST00000396284; = p.A92S on NM_001080770.2) | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as rs201505271; called by muse, mutect2, varscan2
- LCT | c.2291A>T p.N764I | Missense Mutation (SNP) | VAF 19/190 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV99930344; called by muse, mutect2, varscan2
- MAP1A | c.5634G>A p.W1878* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as COSV100289169; called by muse, mutect2, varscan2
- METTL14 | c.880G>A p.G294R | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101183415; called by muse, mutect2, varscan2
- MID2 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 82/147 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs373511106, COSV53309722; called by muse, mutect2, varscan2
- NDUFAF4 | c.174T>A p.D58E | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV100294138; called by muse, mutect2
- PALM2AKAP2 | c.2389G>A p.G797R (on ENST00000259318 / NM_001136562.3; = p.G1028R on NM_007203.5) | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755671487, COSV99395675; called by muse, mutect2, varscan2
- PCDHGB4 | c.1600G>A p.D534N | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99546029; called by muse, mutect2, varscan2
- RTP3 | c.670G>A p.V224M | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.52); catalogued as rs781418653, COSV99946990; called by muse, mutect2, varscan2
- SHC3 | c.505A>G p.M169V | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs200962607, COSV101012054; called by muse, mutect2, varscan2
- SLC12A7 | c.2876C>T p.A959V | Missense Mutation (SNP) | VAF 19/232 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as rs199620140; called by muse, mutect2
- TOX | c.905T>G p.L302* | Nonsense Mutation (SNP) | VAF 45/95 reads (47%) | catalogued as COSV100813086; called by muse, mutect2, varscan2
- VWA3A | c.3037G>A p.V1013M | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.428); catalogued as rs1312820883, COSV100241282; called by muse, mutect2
- XRCC5 | c.44A>G p.D15G | Missense Mutation (SNP) | VAF 60/139 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101079847; called by muse, mutect2, varscan2
- CIC | c.3110_3113del p.S1037* | Frame Shift Del (DEL) | VAF 5/32 reads (16%) | called by mutect2, pindel, varscan2
- H1-4 | c.365_366del p.K122Sfs*73 | Frame Shift Del (DEL) | VAF 6/47 reads (13%) | called by mutect2, pindel
- SVEP1 | c.2517C>T p.D839= | Silent (SNP) | VAF 21/134 reads (16%) | catalogued as rs751125933, COSV100238936; called by muse, mutect2, varscan2
- SLC35A3 | c.*375G>A | 3'UTR (SNP) | VAF 12/43 reads (28%) | catalogued as COSV64515853; called by muse, mutect2, varscan2
